Somatic mutation profile of tumor specimen C3L-08145-01 (aliquot CPT0511150006) from CPTAC case C3L-08145, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 71.9 years (26,266 days).
Specimen C3L-08145-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d59d0373-ece0-459f-a5ac-5397e4e63875.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08145-31 (Blood Derived Normal), aliquot CPT0511140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/331b6d7e-629f-43a9-8a6c-fd60f239a5ad

The open-access MAF lists 1,235 somatic variants for this specimen: 881 protein-altering or splice-affecting, 306 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 627, Silent 306, Frame Shift Del 167, Frame Shift Ins 35, Nonsense Mutation 30, Intron 28, In Frame Del 8, Splice Site 7, Splice Region 7, 5'Flank 5, 3'Flank 5, 5'UTR 5.

Variants (750 of 1,235; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 15/122 reads (12%) | catalogued as rs122445108, CM000004; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- LMNA | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 84/616 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs769561386, CM064113, COSV61541870; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MYLK | c.4438C>T p.R1480* | Nonsense Mutation (SNP) | VAF 32/244 reads (13%) | catalogued as rs387906782, CM107674, COSV99051919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.6707del p.N2236Tfs*29 | Frame Shift Del (DEL) | VAF 18/199 reads (9%) | catalogued as rs797045778; ClinVar: pathogenic; called by mutect2, pindel
- NPHS2 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780761368, CM021650, COSV62635857; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530318579, CD077427, CM042095, COSV62635119; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- RPGRIP1L | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 23/226 reads (10%) | catalogued as rs1037406858; ClinVar: pathogenic; called by muse, mutect2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 48/267 reads (18%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- AARS2 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 62/480 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs753428388; called by muse, mutect2, varscan2
- ABCA13 | c.8816G>A p.R2939H | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs553514517, COSV101447300; called by muse, mutect2, varscan2
- ADAM33 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 80/674 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100598040; called by muse, mutect2, varscan2
- ADAMTS2 | c.1508G>A p.C503Y | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1200406485, COSV51087532; called by muse, mutect2
- ADAMTSL2 | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 62/487 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs143689251; called by muse, mutect2, varscan2
- ADGRA3 | c.1984C>T p.R662* | Nonsense Mutation (SNP) | VAF 27/286 reads (9%) | catalogued as COSV99293443; called by muse, mutect2
- ADGRD2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 38/876 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as rs1453322629; called by muse, mutect2
- ADGRG7 | c.2026G>A p.V676I | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs749484238; called by muse, mutect2, varscan2
- ADGRL3 | c.2649C>A p.N883K (on ENST00000506720 / NM_001322402.2; = p.N815K on NM_015236.6) | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs747899520; called by muse, mutect2
- AK1 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1414427449; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 31/272 reads (11%) | catalogued as COSV62339755; called by mutect2, varscan2
- ALDH3B1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 35/448 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as rs779318898; called by muse, mutect2
- ALG1L2 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 46/481 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs748693602; called by muse, mutect2, varscan2
- ANKMY1 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 54/462 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs753004543, COSV56034229; called by muse, mutect2, varscan2
- ANKRD46 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 57/478 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.595); catalogued as rs765571492, COSV59516178; called by muse, mutect2, varscan2
- ANKRD9 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 103/813 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1267162678; called by muse, mutect2, varscan2
- ANKUB1 | c.629G>A p.W210* | Nonsense Mutation (SNP) | VAF 13/439 reads (3%) | catalogued as rs1383731046; called by muse, mutect2
- AP1AR | c.308G>T p.R103I | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV56768764; called by muse, varscan2
- AP5B1 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 80/600 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.068); catalogued as rs372842325; called by muse, mutect2, varscan2
- AP5S1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 54/394 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55694293; called by muse, mutect2, varscan2
- ARFGAP1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778968717; called by muse, mutect2, varscan2
- ARHGAP11A | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752987597; called by muse, mutect2
- ARHGAP4 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 43/452 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs782110306; called by muse, mutect2, varscan2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 52/326 reads (16%) | catalogued as rs965020534; called by mutect2, varscan2
- ARPP21 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 50/364 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1478885794, COSV51791322; called by muse, mutect2, varscan2
- AVPR1B | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 76/650 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs368239814; called by muse, mutect2, varscan2
- B4GALNT1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 55/419 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs368334961; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 17/116 reads (15%) | catalogued as COSV59620972; called by mutect2, varscan2
- BAIAP2L2 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 67/630 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs778920958; called by muse, mutect2, varscan2
- BARHL2 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 82/531 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as rs775937644, COSV100966033; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 49/438 reads (11%) | catalogued as rs776003776; called by mutect2, pindel, varscan2
- BNIPL | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 57/456 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs138679997; called by muse, mutect2, varscan2
- BRD2 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs137898499; called by muse, mutect2, varscan2
- BTBD8 | c.5317del p.S1773Pfs*23 (on ENST00000636805 / NM_001376131.1; = p.S1260Pfs*23 on NM_015237.4) | Frame Shift Del (DEL) | VAF 24/262 reads (9%) | catalogued as COSV64883851; called by mutect2, pindel
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 84/386 reads (22%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- C10orf71 | c.2320A>G p.M774V | Missense Mutation (SNP) | VAF 46/456 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1167958396; called by muse, mutect2
- C3 | c.2071C>T p.R691C | Missense Mutation (SNP) | VAF 53/439 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55579741; called by muse, mutect2, varscan2
- C3AR1 | c.1088T>C p.M363T | Missense Mutation (SNP) | VAF 43/421 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs760186269; called by muse, mutect2, varscan2
- C3orf20 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 55/447 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as rs150691724; called by muse, mutect2, varscan2
- C3orf85 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs1030847425; called by muse, mutect2, varscan2
- C8orf34 | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV57410790; called by muse, mutect2
- CACNA1E | c.4763G>A p.R1588H | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62382498; called by muse, mutect2, varscan2
- CACNA2D3 | c.2255T>C p.L752P | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs569277580; called by muse, mutect2
- CACNA2D3 | c.3050G>T p.C1017F | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99868160; called by muse, mutect2
- CACNG6 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs773485518, COSV53168144; called by muse, mutect2, varscan2
- CAMSAP2 | c.4208G>A p.R1403Q (on ENST00000236925 / NM_001297707.2; = p.R1392Q on NM_203459.3) | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52670206; called by muse, varscan2
- CAP2 | c.1418C>A p.A473E | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs1440867205; called by muse, mutect2, varscan2
- CARMIL3 | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 93/594 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57724867; called by muse, varscan2
- CASKIN1 | c.3662C>T p.P1221L | Missense Mutation (SNP) | VAF 94/608 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1221734380, COSV58212981; called by muse, mutect2, varscan2
- CASKIN2 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs149947368; called by muse, mutect2
- CASP5 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99508142; called by muse, mutect2
- CBFA2T2 | c.1321del p.T441Qfs*5 | Frame Shift Del (DEL) | VAF 26/187 reads (14%) | catalogued as COSV100656585; called by mutect2, pindel, varscan2
- CCDC102A | c.1274A>G p.H425R | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs764648298; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 31/146 reads (21%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC170 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 62/428 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99498245; called by muse, mutect2, varscan2
- CDC27 | c.1591T>C p.Y531H | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs539804101; called by muse, mutect2, varscan2
- CDC42EP4 | c.325T>A p.S109T | Missense Mutation (SNP) | VAF 62/527 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1568339758; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 28/218 reads (13%) | catalogued as rs762194001; called by mutect2, varscan2
- CDK5RAP3 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs1490985530, COSV58114979; called by muse, mutect2, varscan2
- CELSR2 | c.3259G>A p.A1087T | Missense Mutation (SNP) | VAF 69/483 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.787); catalogued as rs754419241, COSV54772680; called by muse, mutect2, varscan2
- CEMIP2 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 49/350 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs773716646, COSV65486511; called by muse, mutect2, varscan2
- CEMIP2 | c.790del p.S264Pfs*6 | Frame Shift Del (DEL) | VAF 31/327 reads (9%) | catalogued as COSV65489551; called by mutect2, pindel, varscan2
- CFAP61 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as rs529375058; called by muse, mutect2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 26/147 reads (18%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHRNA2 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 64/443 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs757700781; called by muse, mutect2, varscan2
- CHRNB2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 75/524 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.746); catalogued as rs780175030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLASP2 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 55/504 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919605135; called by muse, mutect2, varscan2
- CLCN4 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 73/568 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1374813094, COSV66465074; called by muse, mutect2, varscan2
- CLNK | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 27/377 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs577423431; called by muse, mutect2
- CLPTM1L | c.837del p.F279Lfs*2 | Frame Shift Del (DEL) | VAF 46/436 reads (11%) | catalogued as rs777479912; called by mutect2, pindel, varscan2
- CMIP | c.1947C>T p.D649= (on ENST00000537098 / NM_198390.2; = p.D555= on NM_030629.3) | Splice Region (SNP) | VAF 24/249 reads (10%) | catalogued as rs781781212, COSV67697583; called by muse, mutect2, varscan2
- CNGB3 | c.1375A>G p.M459V | Missense Mutation (SNP) | VAF 54/374 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV60687822; called by muse, mutect2, varscan2
- CNIH1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as rs747682259, COSV53595347; called by muse, mutect2, varscan2
- COBLL1 | c.3236G>A p.R1079H (on ENST00000392717; = p.R1041H on NM_014900.5) | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs540904114, COSV52067533; called by muse, varscan2
- COG5 | c.1410del p.P472Rfs*19 | Frame Shift Del (DEL) | VAF 42/285 reads (15%) | catalogued as COSV51764686; called by mutect2, pindel, varscan2
- COG6 | c.1619A>G p.Q540R | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100743464; called by muse, mutect2
- COL16A1 | c.4610del p.P1537Qfs*60 | Frame Shift Del (DEL) | VAF 27/220 reads (12%) | catalogued as rs1557598575, COSV54703829; called by mutect2, pindel, varscan2
- CPA6 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs140854092; called by muse, mutect2
- CPXM2 | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749163201, COSV53858145, COSV53863962; called by muse, mutect2, varscan2
- CRTAC1 | c.1439del p.G480Afs*26 | Frame Shift Del (DEL) | VAF 97/454 reads (21%) | catalogued as COSV100085397; called by mutect2, pindel, varscan2
- CRTAC1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 117/474 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs553337222; called by muse, mutect2, varscan2
- CSMD1 | c.9134C>A p.A3045E (on ENST00000520002; = p.A3044E on NM_033225.6) | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as rs1391496203, COSV59383985, COSV59390481; called by muse, mutect2
- CSRP1 | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 15/363 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100384426; called by muse, mutect2
- CTBP1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs145193058; called by muse, mutect2, varscan2
- CTCF | c.2070del p.E691Sfs*30 | Frame Shift Del (DEL) | VAF 48/388 reads (12%) | catalogued as rs1400980130; called by mutect2, pindel, varscan2
- CTU1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 37/781 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1421190350; called by muse, mutect2
- CYBC1 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 57/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139347006; called by muse, mutect2, varscan2
- CYBRD1 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 21/283 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs781047968; called by muse, mutect2
- CYP39A1 | c.65A>G p.Q22R | Missense Mutation (SNP) | VAF 39/359 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs754752969; called by muse, mutect2, varscan2
- DBNL | c.1228C>T p.R410C (on ENST00000448521 / NM_001014436.3; = p.R411C on NM_014063.7) | Missense Mutation (SNP) | VAF 78/475 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs969352844; called by muse, mutect2, varscan2
- DCDC2 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.88); catalogued as rs781510673; ClinVar: uncertain significance; called by muse, varscan2
- DDR1 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 78/669 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.855); catalogued as rs1199682251; called by muse, mutect2, varscan2
- DDX27 | c.1601C>T p.T534M | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374365767; called by muse, mutect2
- DENND1C | c.1650C>A p.F550L | Missense Mutation (SNP) | VAF 78/441 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as rs1488535133; called by muse, mutect2, varscan2
- DGKK | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 34/382 reads (9%) | catalogued as COSV65706472; called by muse, mutect2
- DHX30 | c.2453A>G p.N818S (on ENST00000445061 / NM_138615.3; = p.N779S on NM_014966.3) | Missense Mutation (SNP) | VAF 16/458 reads (3%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV99050067; called by muse, mutect2
- DIDO1 | c.6572G>A p.R2191Q | Missense Mutation (SNP) | VAF 83/665 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs780511586; called by muse, mutect2, varscan2
- DIO2 | c.56del p.F19Sfs*23 | Frame Shift Del (DEL) | VAF 47/380 reads (12%) | catalogued as rs148778534; called by mutect2, pindel, varscan2
- DIS3L2 | c.2629G>A p.G877S | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs765768186; called by muse, mutect2, varscan2
- DLGAP2 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 40/482 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as rs1220942982, COSV101423196; called by muse, mutect2
- DMAP1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 49/520 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401567908, COSV60001341; called by muse, mutect2
- DMGDH | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 47/363 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99668414; called by muse, mutect2, varscan2
- DMRT1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 81/653 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs892845295; called by muse, mutect2, varscan2
- DNAH12 | c.3383C>T p.T1128M (on ENST00000351747; = p.T1151M on NM_001366028.2) | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs372611509; called by muse, mutect2, varscan2
- DNAH5 | c.7475C>T p.A2492V | Missense Mutation (SNP) | VAF 46/645 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs529080443, COSV99455587; ClinVar: uncertain significance; called by muse, mutect2
- DNAI3 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs199712026; called by muse, mutect2, varscan2
- DNAJB7 | c.884del p.K295Rfs*25 | Frame Shift Del (DEL) | VAF 29/213 reads (14%) | catalogued as rs768619916; called by mutect2, varscan2
- DNAJC11 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 36/281 reads (13%) | catalogued as rs1232676529, COSV53787684; called by muse, varscan2
- DNASE1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.251); catalogued as rs8176939, CM144167; called by muse, mutect2, varscan2
- DPP10 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.744); catalogued as COSV59678436; called by muse, mutect2, varscan2
- DPY19L3 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.974); catalogued as rs775762339, COSV60475780; called by muse, mutect2, varscan2
- DRICH1 | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 9/229 reads (4%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.801); catalogued as COSV58503113; called by muse, mutect2
- DUS3L | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 67/441 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs1451865334, COSV57833520; called by muse, mutect2, varscan2
- DUSP14 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 60/541 reads (11%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.731); catalogued as rs1370928384; called by muse, mutect2, varscan2
- DYNC1H1 | c.483del p.F161Lfs*52 | Frame Shift Del (DEL) | VAF 29/241 reads (12%) | catalogued as rs1566996283; called by mutect2, pindel, varscan2
- EFNB1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 75/653 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as rs758554867, COSV99214733; called by muse, mutect2, varscan2
- EPHA10 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 69/583 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57625087; called by muse, mutect2, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 26/205 reads (13%) | catalogued as rs756461692; called by mutect2, varscan2
- ERBIN | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as COSV52327679; called by muse, mutect2, varscan2
- ERCC2 | c.1801C>T p.R601W | Missense Mutation (SNP) | VAF 70/406 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753641926, CM010228, COSV67269580, COSV67269695; called by muse, mutect2, varscan2
- ERLIN2 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 42/353 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.272); catalogued as rs149254654, COSV99379780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERVMER34-1 | c.899del p.L300Cfs*33 | Frame Shift Del (DEL) | VAF 48/366 reads (13%) | catalogued as rs779855268; called by mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 43/311 reads (14%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOC3 | c.1676C>T p.T559M | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778771036; called by muse, mutect2, varscan2
- F8 | c.4681G>A p.G1561R | Missense Mutation (SNP) | VAF 56/463 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.77); catalogued as rs1557278372; called by muse, mutect2, varscan2
- FAM153B | c.280C>T p.R94W (on ENST00000253490; = p.R17W on NM_001265615.1) | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.759); catalogued as rs765334549; called by muse, varscan2
- FAM178B | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 19/452 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1027565687; called by muse, mutect2
- FAM181A | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 81/593 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.675); catalogued as rs371287987; called by muse, mutect2, varscan2
- FAM53B | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766011933; called by muse, mutect2
- FAM83H | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 114/961 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1554623098, COSV66354083; called by muse, mutect2, varscan2
- FANCG | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 39/372 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138395184; called by muse, mutect2, varscan2
- FBF1 | c.247G>A p.G83S (on ENST00000586717; = p.G97S on NM_001319193.1) | Missense Mutation (SNP) | VAF 25/312 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs761998543; called by muse, mutect2
- FBN2 | c.3200G>A p.G1067E | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52505820; called by muse, mutect2, varscan2
- FBN2 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 49/744 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as rs1040280257; called by muse, mutect2
- FHOD3 | c.2933del p.P978Lfs*10 (on ENST00000359247 / NM_001281739.3; = p.P995Lfs*10 on NM_025135.5) | Frame Shift Del (DEL) | VAF 46/406 reads (11%) | catalogued as rs1289548251; called by mutect2, pindel, varscan2
- FKBP10 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 39/402 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201861640; called by muse, mutect2, varscan2
- FOXK1 | c.1697-1G>T p.X566_splice | Splice Site (SNP) | VAF 41/321 reads (13%) | catalogued as COSV61068649; called by muse, mutect2, varscan2
- FSIP2 | c.12712C>T p.R4238* | Nonsense Mutation (SNP) | VAF 25/159 reads (16%) | catalogued as rs1160663250; called by muse, mutect2, varscan2
- GAL3ST1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 84/629 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs985871403, COSV58893711; called by muse, varscan2
- GALNT9 | c.1631C>T p.A544V (on ENST00000328957 / NM_001122636.2; = p.A178V on NM_021808.3) | Missense Mutation (SNP) | VAF 46/397 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs778169495, COSV61095905; called by muse, mutect2, varscan2
- GAPDHS | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 64/458 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs760185950; called by muse, mutect2, varscan2
- GBA | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 34/359 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV59169266; called by muse, mutect2, varscan2
- GCC2 | c.2135del p.L712Cfs*16 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs777909420; called by mutect2, pindel, varscan2
- GEMIN5 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147970218; called by muse, mutect2, varscan2
- GGCX | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 47/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142918177, COSV99289925; called by muse, mutect2, varscan2
- GJA10 | c.989G>C p.G330A | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1321759813; called by muse, mutect2, varscan2
- GLS | c.1503G>A p.W501* | Nonsense Mutation (SNP) | VAF 28/211 reads (13%) | catalogued as COSV104405903; called by muse, mutect2, varscan2
- GNA12 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1041978667; called by muse, mutect2, varscan2
- GNAL | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 29/400 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as rs769324807; called by muse, mutect2
- GPR12 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 38/419 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.322); catalogued as rs1367653070, COSV67344414; called by muse, mutect2
- GPR21 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 48/486 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1336308949; called by muse, mutect2
- GRIP2 | c.2158G>A p.V720M (on ENST00000619221; = p.V623M on NM_001080423.4) | Missense Mutation (SNP) | VAF 56/381 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.369); catalogued as rs530380433; called by muse, mutect2, varscan2
- GRM5 | c.3596C>T p.T1199I (on ENST00000305447 / NM_001143831.2; = p.T1167I on NM_000842.4) | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as COSV59628982; called by muse, mutect2, varscan2
- GTF3A | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs898575735, COSV63528529; called by muse, mutect2, varscan2
- GTF3C1 | c.3538del p.E1180Kfs*4 | Frame Shift Del (DEL) | VAF 40/340 reads (12%) | catalogued as COSV100649528; called by mutect2, pindel, varscan2
- H2AC6 | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); catalogued as rs755810991; called by muse, mutect2, varscan2
- HDGFL2 | c.1702_1704del p.K568del | In Frame Del (DEL) | VAF 85/541 reads (16%) | catalogued as rs752894033; called by mutect2, pindel, varscan2
- HOGA1 | c.122del p.P41Lfs*2 | Frame Shift Del (DEL) | VAF 129/526 reads (25%) | catalogued as CM122019; called by mutect2, pindel, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 52/392 reads (13%) | catalogued as rs755016625; called by mutect2, varscan2
- HSD17B14 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as rs758469349; called by muse, mutect2, varscan2
- HTR1D | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 81/566 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.123); catalogued as rs766858162, COSV100024808, COSV100024892; called by muse, mutect2, varscan2
- IDH1 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV61619722; called by muse, mutect2, varscan2
- IFRD2 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 40/467 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs782225359; called by muse, mutect2
- IGSF22 | c.2355G>T p.Q785H (on ENST00000319338; = p.Q886H on NM_173588.4) | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs754290071, COSV60038718; called by muse, mutect2, varscan2
- IGSF9B | c.4216C>T p.R1406W | Missense Mutation (SNP) | VAF 55/571 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1357721454; called by muse, mutect2
- IKBKB | c.1673del p.G558Efs*6 | Frame Shift Del (DEL) | VAF 41/392 reads (10%) | catalogued as rs1563361838; called by mutect2, pindel, varscan2
- INSYN2B | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 49/359 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs375956500; called by muse, mutect2, varscan2
- IRS2 | c.3512G>A p.R1171H | Missense Mutation (SNP) | VAF 86/629 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1021457672; called by muse, varscan2
- ITGAD | c.965G>A p.G322D | Missense Mutation (SNP) | VAF 52/378 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV66758954; called by muse, mutect2, varscan2
- ITPR1 | c.4079G>A p.R1360Q (on ENST00000354582; = p.R1345Q on NM_002222.7) | Missense Mutation (SNP) | VAF 43/369 reads (12%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.997); catalogued as rs1461379244, COSV100233638; called by muse, mutect2, varscan2
- KCNJ16 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 46/409 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.401); catalogued as rs1016980056; called by muse, mutect2, varscan2
- KCTD17 | c.815C>T p.P272L (on ENST00000403888 / NM_001282684.1; = p.P248L on NM_024681.3) | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755400870; called by muse, mutect2, varscan2
- KDM4B | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 83/463 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); catalogued as rs576623184, COSV50260553; called by muse, mutect2, varscan2
- KIAA1217 | c.29A>T p.E10V | Missense Mutation (SNP) | VAF 31/308 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.907); catalogued as rs758713857; called by muse, mutect2, varscan2
- KIAA1549 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 46/409 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs771107330, COSV54313939; called by muse, mutect2, varscan2
- KIF19 | c.2464C>T p.R822W | Missense Mutation (SNP) | VAF 54/790 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs768562023; called by muse, mutect2
- KPRP | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 63/541 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs752074154, COSV64220853; called by muse, mutect2, varscan2
- KRT12 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs1169210524, COSV99289239; called by muse, mutect2
- KRT12 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 79/666 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs771841418; called by muse, mutect2, varscan2
- KRTAP10-9 | c.499A>G p.S167G | Missense Mutation (SNP) | VAF 54/634 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs782444744; called by muse, mutect2
- LDB3 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as rs573061464, COSV53937632; ClinVar: uncertain significance; called by muse, varscan2
- LENG8 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 18/658 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100418270; called by muse, mutect2
- LGALS9 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs376414950; called by muse, mutect2, varscan2
- LINGO2 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs199551773, COSV58056464; called by muse, mutect2, varscan2
- LRP1B | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as rs1180082899; called by muse, mutect2, varscan2
- LRRD1 | c.1396del p.I466* | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | catalogued as rs756444234; called by mutect2, pindel, varscan2
- MACF1 | c.14882G>A p.R4961H (on ENST00000372915; = p.R2894H on NM_012090.5) | Missense Mutation (SNP) | VAF 59/358 reads (16%) | catalogued as rs778785908, COSV57134657; called by muse, mutect2, varscan2
- MAGEE2 | c.1552T>G p.F518V | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV64897725; called by muse, mutect2, varscan2
- MAK | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57564024, COSV57565517; called by muse, mutect2
- MAP11 | c.665del p.P222Lfs*4 | Frame Shift Del (DEL) | VAF 40/406 reads (10%) | catalogued as rs35930156; called by mutect2, pindel, varscan2
- MAP1S | c.959dup p.S321Lfs*34 | Frame Shift Ins (INS) | VAF 108/720 reads (15%) | catalogued as rs1334124663; called by mutect2, pindel, varscan2
- MAP3K1 | c.3278A>G p.D1093G | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1290994534; called by muse, mutect2, varscan2
- MAP3K14 | c.2639G>A p.R880Q | Missense Mutation (SNP) | VAF 46/451 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.373); catalogued as rs772349799; called by muse, mutect2
- MAPK7 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 62/553 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs752892599, COSV55191189; called by muse, mutect2, varscan2
- MBD2 | c.20del p.G7Efs*26 | Frame Shift Del (DEL) | VAF 37/332 reads (11%) | catalogued as rs1301242496; called by mutect2, pindel
- MCAT | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 50/407 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs765693023, COSV51791790; called by muse, mutect2, varscan2
- MCOLN1 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 69/503 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as rs549648443, COSV99900495; called by muse, mutect2, varscan2
- MDC1 | c.3646G>A p.D1216N | Missense Mutation (SNP) | VAF 96/649 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs778637501; called by muse, mutect2, varscan2
- MDGA1 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 74/688 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1561843973; called by muse, mutect2, varscan2
- MDN1 | c.16495C>T p.R5499* | Nonsense Mutation (SNP) | VAF 16/396 reads (4%) | catalogued as rs1242203123, COSV65517374; called by muse, mutect2
- MED25 | c.310A>G p.M104V | Missense Mutation (SNP) | VAF 58/388 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs1321456059; called by muse, mutect2, varscan2
- METTL11B | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748895385; called by muse, mutect2, varscan2
- MGST2 | c.58+2_58+5del p.X20_splice | Splice Site (DEL) | VAF 27/216 reads (13%) | catalogued as rs1476814375; called by pindel, varscan2
- MMS22L | c.2799del p.V934Ffs*8 | Frame Shift Del (DEL) | VAF 13/109 reads (12%) | catalogued as rs1562416103; called by mutect2, pindel, varscan2
- MRC2 | c.3377C>A p.P1126Q | Missense Mutation (SNP) | VAF 76/591 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.579); catalogued as COSV100316891; called by muse, mutect2, varscan2
- MROH2A | c.1766C>A p.P589H | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67682430; called by muse, mutect2
- MSI1 | c.345del p.L116Cfs*3 | Frame Shift Del (DEL) | VAF 51/417 reads (12%) | catalogued as rs748469666; called by mutect2, pindel, varscan2
- MST1 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs111260825; called by muse, mutect2, varscan2
- MTERF1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs1322509194; called by muse, mutect2, varscan2
- MUC3A | c.8918C>T p.P2973L | Missense Mutation (SNP) | VAF 70/1130 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.031); catalogued as rs577819188; called by muse, mutect2
- MUC4 | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 66/642 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.55); catalogued as rs373318989; called by muse, mutect2, varscan2
- MYBBP1A | c.116_118del p.F39del | In Frame Del (DEL) | VAF 56/508 reads (11%) | catalogued as rs773492683; called by pindel, varscan2
- MYCBP2 | c.13430A>G p.H4477R (on ENST00000357337; = p.H4515R on NM_015057.5) | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs1315006250; called by muse, mutect2, varscan2
- MYH10 | c.5108G>A p.R1703H | Missense Mutation (SNP) | VAF 54/352 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs769105110; called by muse, mutect2, varscan2
- MYH14 | c.3901C>T p.R1301* | Nonsense Mutation (SNP) | VAF 41/359 reads (11%) | catalogued as rs748162920; called by muse, mutect2, varscan2
- MYH14 | c.4469G>A p.R1490Q | Missense Mutation (SNP) | VAF 75/563 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.93); catalogued as rs768724541, COSV99222172; called by muse, mutect2, varscan2
- MYH7 | c.3475G>A p.V1159M | Missense Mutation (SNP) | VAF 33/601 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs730880776; ClinVar: uncertain significance; called by muse, mutect2
- MYO15A | c.7090G>A p.A2364T | Missense Mutation (SNP) | VAF 43/342 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1392202025; called by muse, mutect2, varscan2
- MYO15A | c.8261C>T p.T2754M | Missense Mutation (SNP) | VAF 48/473 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as rs766544188, COSV52761217; called by muse, mutect2, varscan2
- MYO16 | c.3974C>T p.A1325V | Missense Mutation (SNP) | VAF 51/417 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs1460924180, COSV62745786; called by muse, mutect2
- MYO18B | c.7154G>A p.R2385Q | Missense Mutation (SNP) | VAF 62/495 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.226); catalogued as rs982421225; called by muse, mutect2, varscan2
- MYT1L | c.504C>T p.N168= | Splice Region (SNP) | VAF 21/262 reads (8%) | catalogued as rs758684369, COSV67720555; called by muse, mutect2
- N4BP2L2 | c.759A>G p.I253M | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV57228513; called by muse, mutect2, varscan2
- NAGPA | c.492del p.L165Cfs*35 | Frame Shift Del (DEL) | VAF 82/619 reads (13%) | catalogued as rs761809784, COSV100392824; called by mutect2, pindel, varscan2
- NCAM1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.545); catalogued as COSV57520104; called by muse, mutect2, varscan2
- NCOR1 | c.4123C>T p.R1375W | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1276291276, COSV99251941; called by muse, mutect2, varscan2
- NEURL1B | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 54/478 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.036); catalogued as rs1280673797; called by muse, varscan2
- NF1 | c.7534G>A p.G2512S (on ENST00000358273 / NM_001042492.3; = p.G2491S on NM_000267.3) | Missense Mutation (SNP) | VAF 44/382 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as rs766496842, COSV62196835, COSV62217453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP11 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.129); catalogued as rs374529395; called by muse, mutect2, varscan2
- NOTCH3 | c.5404dup p.A1802Gfs*8 | Frame Shift Ins (INS) | VAF 64/430 reads (15%) | catalogued as rs753725730; called by mutect2, varscan2
- NPAS1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 81/487 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.425); catalogued as rs781209604, COSV71383855; called by muse, mutect2, varscan2
- NPC1 | c.3560C>T p.A1187V | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as rs113371321, CM096666, CM162520, COSV52573233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR2F6 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 106/674 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs994605622; called by muse, mutect2, varscan2
- NR6A1 | c.968C>T p.T323M (on ENST00000487099 / NM_033334.4; = p.T318M on NM_001489.5) | Missense Mutation (SNP) | VAF 66/455 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1488179673, COSV60637898; called by muse, mutect2, varscan2
- NSD1 | c.1727dup p.N576Kfs*8 | Frame Shift Ins (INS) | VAF 42/426 reads (10%) | catalogued as rs1299932363; called by mutect2, pindel
- NTNG1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs142686945; called by muse, mutect2, varscan2
- NUPR2 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 57/430 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs894127818, COSV61409006; called by muse, mutect2, varscan2
- NUTM2G | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 39/379 reads (10%) | catalogued as rs530495768; called by muse, mutect2, varscan2
- OBSCN | c.15221G>A p.R5074H | Missense Mutation (SNP) | VAF 49/441 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs570286923; called by muse, mutect2, varscan2
- OPRK1 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs202165724, COSV55570192; called by muse, mutect2, varscan2
- OR10J3 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 49/483 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100171945, COSV59954527; called by muse, mutect2, varscan2
- OR1A1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 40/361 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs752953337, COSV58403164; called by muse, mutect2, varscan2
- OTOP1 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 25/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757334904; called by muse, mutect2
- OTP | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 78/579 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as rs1290424083; called by muse, mutect2, varscan2
- P2RX4 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 38/443 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); catalogued as rs778635181; called by muse, mutect2
- PABPC5 | c.889A>C p.S297R | Missense Mutation (SNP) | VAF 66/507 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57041642; called by muse, mutect2, varscan2
- PCDH10 | c.360dup p.S121Lfs*13 | Frame Shift Ins (INS) | VAF 74/528 reads (14%) | catalogued as rs759095467; called by mutect2, varscan2
- PCDH10 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 39/779 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV52089594; called by muse, mutect2
- PCDH15 | c.5462C>A p.P1821Q | Missense Mutation (SNP) | VAF 46/396 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as rs1474035683; called by muse, mutect2, varscan2
- PCDHA8 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 52/283 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV100970994; called by muse, mutect2, varscan2
- PCDHB16 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 44/670 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.65); catalogued as rs368338519; called by muse, mutect2
- PCDHGA1 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 38/351 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV100965930; called by muse, mutect2, varscan2
- PCNX2 | c.1856del p.K619Rfs*52 | Frame Shift Del (DEL) | VAF 19/185 reads (10%) | catalogued as COSV50784264; called by mutect2, pindel, varscan2
- PCOLCE2 | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 40/323 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as rs762154075, COSV56000491; called by muse, mutect2, varscan2
- PCYT1A | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 47/353 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375261933; called by muse, mutect2, varscan2
- PDCD10 | c.211del p.S71Afs*18 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | catalogued as CD143177; called by mutect2, pindel, varscan2
- PDYN | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 70/506 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150455107; called by muse, mutect2, varscan2
- PDZD2 | c.4448C>T p.P1483L | Missense Mutation (SNP) | VAF 66/646 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1470302431; called by muse, mutect2, varscan2
- PHEX | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs749081778; called by muse, mutect2, varscan2
- PHIP | c.4282G>A p.A1428T | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as rs776235031; called by muse, mutect2, varscan2
- PHKB | c.2160G>T p.K720N | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs774334485; called by muse, mutect2, varscan2
- PIGT | c.1043del p.P348Qfs*11 | Frame Shift Del (DEL) | VAF 38/311 reads (12%) | catalogued as rs749895437; called by mutect2, pindel, varscan2
- PIK3C2B | c.3722C>T p.A1241V | Missense Mutation (SNP) | VAF 44/425 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1201752006; called by muse, mutect2
- PLEC | c.6041G>A p.R2014Q (on ENST00000322810 / NM_201380.4; = p.R1904Q on NM_000445.5) | Missense Mutation (SNP) | VAF 103/812 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs932283077, COSV59631487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA8 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); catalogued as rs1174554720; called by muse, mutect2
- PLPP7 | c.149del p.P50Hfs*24 | Frame Shift Del (DEL) | VAF 61/603 reads (10%) | catalogued as COSV64836143; called by mutect2, varscan2
- PLPPR5 | c.621+1G>A p.X207_splice | Splice Site (SNP) | VAF 25/145 reads (17%) | catalogued as rs1385762963, COSV54171048; called by muse, mutect2, varscan2
- PLXDC1 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs1281673061; called by muse, mutect2, varscan2
- PLXNB3 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 111/765 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs782540845; called by muse, mutect2, varscan2
- PLXNC1 | c.288del p.A97Rfs*46 | Frame Shift Del (DEL) | VAF 82/842 reads (10%) | catalogued as rs1555192596; called by mutect2, pindel
- POLE | c.2515G>T p.G839W | Missense Mutation (SNP) | VAF 53/403 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367964261; called by muse, mutect2, varscan2
- POLR3A | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1262335730, COSV100965512; called by muse, mutect2
- POU3F4 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 55/544 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1421127773, COSV64537552; called by muse, mutect2
- PPARGC1B | c.2398G>A p.G800S | Missense Mutation (SNP) | VAF 57/462 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.224); catalogued as rs751959516; called by muse, mutect2, varscan2
- PPP1R21 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.701); catalogued as rs750571150; called by muse, mutect2, varscan2
- PPP1R26 | c.3161del p.G1054Afs*100 | Frame Shift Del (DEL) | VAF 72/738 reads (10%) | catalogued as rs1554733377; called by mutect2, pindel
- PPP1R3A | c.2065del p.R689Efs*7 | Frame Shift Del (DEL) | VAF 26/246 reads (11%) | catalogued as rs753380860; called by mutect2, varscan2
- PQBP1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 65/459 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs1557041015; called by muse, mutect2, varscan2
- PRAMEF12 | c.1057C>A p.L353M | Missense Mutation (SNP) | VAF 60/555 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV63216172; called by muse, mutect2, varscan2
- PRPF3 | c.1627A>G p.I543V | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782256620; called by muse, mutect2
- PRR19 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 85/544 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.845); catalogued as rs764318193; called by muse, mutect2, varscan2
- PTEN | c.170del p.L57Wfs*42 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as COSV64290332; called by mutect2, pindel, varscan2
- PTPN14 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 102/550 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs760136630; called by muse, mutect2, varscan2
- PTPRB | c.5572A>T p.R1858* | Nonsense Mutation (SNP) | VAF 34/312 reads (11%) | catalogued as COSV54242142; called by muse, mutect2, varscan2
- PTPRS | c.3072del p.V1025Sfs*18 | Frame Shift Del (DEL) | VAF 60/522 reads (11%) | catalogued as rs756013055, COSV53629833; called by mutect2, pindel, varscan2
- PTPRS | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 80/630 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.416); catalogued as rs750721878, COSV53638505; called by muse, mutect2, varscan2
- PYGL | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 47/332 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53588574; called by muse, mutect2, varscan2
- RBM20 | c.1222del p.L408Sfs*17 | Frame Shift Del (DEL) | VAF 98/403 reads (24%) | catalogued as COSV65704142; called by mutect2, pindel, varscan2
- RBM33 | c.1077G>A p.M359I | Missense Mutation (SNP) | VAF 73/641 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs769200506; called by muse, mutect2, varscan2
- RCOR3 | c.397del p.T133Lfs*7 | Frame Shift Del (DEL) | VAF 26/133 reads (20%) | catalogued as COSV65365594; called by mutect2, pindel, varscan2
- RETREG2 | c.61_66del p.S21_L22del | In Frame Del (DEL) | VAF 56/548 reads (10%) | catalogued as rs1215545885; called by mutect2, pindel, varscan2
- RETSAT | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 56/474 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs375130450; called by muse, mutect2, varscan2
- RIMS2 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV68113049; called by muse, mutect2, varscan2
- RIPK2 | c.514A>G p.M172V | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs751621342; called by muse, mutect2, varscan2
- RNF168 | c.1553del p.N518Ifs*6 | Frame Shift Del (DEL) | VAF 36/360 reads (10%) | catalogued as COSV100534953; called by mutect2, pindel, varscan2
- RNF17 | c.1901A>G p.D634G | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV55048140; called by muse, mutect2, varscan2
- ROBO1 | c.3142A>G p.N1048D | Missense Mutation (SNP) | VAF 19/252 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.191); catalogued as COSV101459085; called by muse, mutect2
- RPRM | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 60/502 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57989291; called by muse, mutect2, varscan2
- RTCB | c.736dup p.M246Nfs*6 | Frame Shift Ins (INS) | VAF 48/376 reads (13%) | catalogued as rs771992011; called by mutect2, varscan2
- RTF1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1469239838, COSV67478413; called by muse, mutect2, varscan2
- RTN3 | c.1651dup p.T551Nfs*3 (on ENST00000377819 / NM_001265589.2; = p.T532Nfs*3 on NM_201428.3) | Frame Shift Ins (INS) | VAF 31/234 reads (13%) | catalogued as rs780998896; called by mutect2, pindel, varscan2
- SAGE1 | c.823G>T p.G275W | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV61011679; called by muse, mutect2
- SAP30BP | c.243del p.K81Nfs*63 | Frame Shift Del (DEL) | VAF 36/265 reads (14%) | catalogued as rs1242431237; called by mutect2, pindel, varscan2
- SCAF11 | c.3232C>T p.R1078C | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1187212662; called by muse, mutect2
- SCLT1 | c.1649A>G p.H550R | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs776998041; called by muse, mutect2, varscan2
- SCNN1B | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 64/528 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852706, CM961267; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- SCUBE2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs781504085; called by muse, mutect2, varscan2
- SDK2 | c.5041G>A p.A1681T | Missense Mutation (SNP) | VAF 47/407 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1320833906; called by muse, mutect2, varscan2
- SEL1L2 | c.585G>T p.M195I | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV53153364; called by muse, mutect2
- SELENBP1 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.155); catalogued as rs750981873, COSV64373624; called by muse, mutect2
- SEMA4F | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 44/345 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs186197606, COSV60284489; called by muse, mutect2, varscan2
- SETD1A | c.2623A>G p.I875V | Missense Mutation (SNP) | VAF 52/600 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs900741601; called by muse, mutect2
- SFRP2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 55/541 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs1256791588, COSV56838054; called by muse, mutect2, varscan2
- SHANK1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 39/369 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459706968, COSV53241893; called by muse, mutect2, varscan2
- SIGIRR | c.1061G>A p.G354D | Missense Mutation (SNP) | VAF 95/683 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs943413918; called by muse, mutect2, varscan2
- SIK2 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 34/380 reads (9%) | catalogued as COSV59253836; called by muse, mutect2
- SIPA1L1 | c.3205C>T p.Q1069* | Nonsense Mutation (SNP) | VAF 47/396 reads (12%) | catalogued as rs1324240468; called by muse, mutect2, varscan2
- SLC17A6 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 57/582 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474042544, COSV54137681, COSV54142917; called by muse, mutect2
- SLC25A38 | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1447803374; called by muse, mutect2, varscan2
- SLC30A1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 90/656 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as rs138833626; called by muse, mutect2, varscan2
- SLC30A10 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 89/709 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs1182791412, COSV63074723; called by muse, mutect2, varscan2
- SLC35B1 | c.746C>T p.S249L (on ENST00000649906; = p.S212L on NM_005827.4) | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs753717821, COSV53602892; called by muse, mutect2, varscan2
- SLC39A4 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 43/712 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1554874182; called by muse, mutect2
- SMAD6 | c.1296del p.G433Afs*106 | Frame Shift Del (DEL) | VAF 56/479 reads (12%) | catalogued as rs751440011; called by mutect2, varscan2
- SMARCA1 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 29/204 reads (14%) | catalogued as rs763343505, COSV64412759; called by muse, mutect2, varscan2
- SMARCB1 | c.214del p.T72Qfs*13 | Frame Shift Del (DEL) | VAF 39/284 reads (14%) | catalogued as COSV99574633; called by mutect2, pindel, varscan2
- SORBS2 | c.842G>A p.R281Q (on ENST00000284776 / NM_021069.5; = p.R374Q on NM_003603.6) | Missense Mutation (SNP) | VAF 54/424 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs376521033; called by muse, mutect2, varscan2
- SOX30 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99398662; called by muse, mutect2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 34/254 reads (13%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPTAN1 | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs777328879; called by muse, mutect2, varscan2
- SPTAN1 | c.2888C>T p.T963M | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs375623472; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SREBF2 | c.3037C>T p.R1013W | Missense Mutation (SNP) | VAF 19/577 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1032566999; called by muse, mutect2
- SRPK1 | c.1460del p.N487Mfs*7 | Frame Shift Del (DEL) | VAF 29/215 reads (13%) | catalogued as rs1561978130; called by mutect2, pindel, varscan2
- SRRM1 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 46/345 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs768701929; called by muse, mutect2, varscan2
- ST6GAL2 | c.337del p.S113Hfs*61 | Frame Shift Del (DEL) | VAF 43/432 reads (10%) | catalogued as rs1327855726; called by mutect2, pindel, varscan2
- STAT6 | c.1547A>G p.Q516R | Missense Mutation (SNP) | VAF 80/411 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55667313; called by muse, mutect2, varscan2
- STAU1 | c.616C>T p.R206W (on ENST00000371856 / NM_001319135.1; = p.R125W on NM_004602.3) | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs143151409; called by muse, mutect2, varscan2
- SYCP2 | c.2465G>A p.R822K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV62767009, COSV62770877; called by muse, mutect2, varscan2
- TAF4 | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 31/678 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs1485615733, COSV53334303; called by muse, mutect2
- TAPBP | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 86/1088 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.913); catalogued as rs984137167; called by muse, mutect2
- TAS1R1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 65/388 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199550568; called by muse, mutect2, varscan2
- TBCD | c.3374G>A p.R1125Q | Missense Mutation (SNP) | VAF 46/421 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754043602; called by muse, mutect2, varscan2
- TDRD6 | c.2053G>T p.G685W | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs752098214; called by muse, mutect2, varscan2
- TENM1 | c.6140G>T p.R2047L | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64438225; called by muse, mutect2, varscan2
- TEPSIN | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 45/350 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs747438452, COSV56143154; called by muse, mutect2, varscan2
- TEX10 | c.2617C>A p.L873I | Missense Mutation (SNP) | VAF 19/388 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV52444365; called by muse, mutect2
- TJP1 | c.3038T>C p.M1013T | Missense Mutation (SNP) | VAF 43/318 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV100632963; called by muse, mutect2, varscan2
- TMC4 | c.1453T>C p.Y485H (on ENST00000617472 / NM_001145303.3; = p.Y479H on NM_144686.4) | Missense Mutation (SNP) | VAF 75/486 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776886781; called by muse, mutect2, varscan2
- TMCC2 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV58006484; called by muse, mutect2, varscan2
- TMEM145 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 79/554 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV52076872; called by muse, mutect2, varscan2
- TMEM17 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs1558722710, COSV100107786; called by muse, mutect2
- TMTC1 | c.1790G>A p.R597Q (on ENST00000539277 / NM_001193451.2; = p.R489Q on NM_175861.3) | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.082); catalogued as rs745880933, COSV55476001; called by muse, varscan2
- TNRC18 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 90/702 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs758416362; called by muse, mutect2, varscan2
- TP53BP1 | c.5451del p.C1818Afs*55 | Frame Shift Del (DEL) | VAF 45/338 reads (13%) | catalogued as COSV53017839; called by mutect2, pindel, varscan2
- TPM1 | c.45G>T p.K15N | Missense Mutation (SNP) | VAF 44/391 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199476301, CM103032; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- TPR | c.4792C>T p.R1598C | Missense Mutation (SNP) | VAF 27/435 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1364163997, COSV66603167; called by muse, mutect2
- TRABD | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 63/501 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.251); catalogued as rs1257942279, COSV57713255; called by muse, mutect2, varscan2
- TRAM1L1 | c.394del p.S132Lfs*9 | Frame Shift Del (DEL) | VAF 13/147 reads (9%) | catalogued as rs757906221; called by mutect2, pindel, varscan2
- TRAPPC9 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 50/437 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs376735305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAV20 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs748205854; called by muse, mutect2
- TRHR | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769413252, COSV100305190; called by muse, mutect2, varscan2
- TRIM49C | c.979A>T p.S327C | Missense Mutation (SNP) | VAF 35/361 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV71510527, COSV71511634; called by muse, mutect2, varscan2
- TRIM71 | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 47/576 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs982336353, COSV101070479, COSV67470139; called by muse, mutect2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 20/130 reads (15%) | catalogued as rs752676391; called by mutect2, varscan2
- TRPC7 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 22/552 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV61457094; called by muse, mutect2
- TSHZ1 | c.353C>T p.A118V (on ENST00000580243 / NM_001308210.2; = p.A73V on NM_005786.6) | Missense Mutation (SNP) | VAF 25/569 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100433461; called by muse, mutect2
- TTC34 | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 69/956 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs932385253, COSV69009453; called by muse, mutect2
- TYRP1 | c.1200del p.F400Lfs*16 | Frame Shift Del (DEL) | VAF 36/344 reads (10%) | catalogued as rs1563856255; called by mutect2, pindel, varscan2
- UBE2J1 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1384148952; called by muse, mutect2
- UGT2A1 | c.1576del p.R526Efs*57 | Frame Shift Del (DEL) | VAF 10/103 reads (10%) | catalogued as rs1446970084; called by mutect2, pindel, varscan2
- UNC79 | c.4972G>A p.G1658S (on ENST00000393151 / NM_001346218.2; = p.G1481S on NM_020818.5) | Missense Mutation (SNP) | VAF 72/641 reads (11%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.057); catalogued as rs374708384, COSV99827535; called by muse, mutect2, varscan2
- UVSSA | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 57/432 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as rs987383576; called by muse, mutect2, varscan2
- VDAC3 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs752791425, COSV50081353, COSV50081912; called by muse, varscan2
- VIRMA | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 43/361 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771063404, COSV52584821; called by muse, mutect2, varscan2
- VWF | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 49/443 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372495746, CM163373; called by muse, mutect2, varscan2
- WDR90 | c.2845C>T p.R949W | Missense Mutation (SNP) | VAF 64/510 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs762743050; called by muse, mutect2, varscan2
- XRN1 | c.703del p.T235Hfs*19 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | catalogued as rs779316292; called by mutect2, pindel, varscan2
- ZBED1 | c.2021T>A p.V674E | Missense Mutation (SNP) | VAF 30/841 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.031); catalogued as COSV58132650; called by muse, mutect2
- ZBTB20 | c.1298C>T p.P433L (on ENST00000474710 / NM_001164342.2; = p.P360L on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/503 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752208031, COSV100615311; called by muse, mutect2, varscan2
- ZBTB46 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 61/487 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs201899346; called by muse, mutect2, varscan2
- ZC3H7B | c.2903C>T p.A968V | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.04); catalogued as rs1456651041; called by muse, varscan2
- ZCCHC4 | c.718del p.C240Afs*35 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | catalogued as rs1343409476; called by mutect2, pindel, varscan2
- ZFHX3 | c.8557G>A p.A2853T | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.174); catalogued as rs200701402; called by muse, mutect2, varscan2
- ZIC4 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 64/603 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV67174639; called by muse, mutect2, varscan2
- ZKSCAN4 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV66023253, COSV66023726; called by muse, mutect2
- ZNF536 | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 110/672 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV100835077; called by muse, mutect2, varscan2
- ZNF599 | c.1130G>A p.C377Y | Missense Mutation (SNP) | VAF 54/524 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.459); catalogued as rs764143876; called by muse, mutect2, varscan2
- ZNF681 | c.1599del p.Y534Tfs*21 | Frame Shift Del (DEL) | VAF 16/122 reads (13%) | catalogued as COSV68075207; called by mutect2, varscan2
- ZNF683 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 71/402 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62875318; called by muse, mutect2, varscan2
- ZNF737 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376968717; called by muse, mutect2, varscan2
- ZNF746 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 98/849 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1483582866; called by muse, mutect2, varscan2
- ZNF829 | c.1024C>A p.H342N | Missense Mutation (SNP) | VAF 50/381 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101199690; called by muse, mutect2, varscan2
- ZNF835 | c.1207T>C p.S403P | Missense Mutation (SNP) | VAF 94/668 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs970135552, COSV73379466; called by muse, mutect2, varscan2
- ZSCAN10 | c.1432C>T p.R478C (on ENST00000252463; = p.R533C on NM_032805.3) | Missense Mutation (SNP) | VAF 92/793 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV99373748; called by muse, mutect2, varscan2
- ZSCAN12 | c.1401del p.K467Nfs*109 | Frame Shift Del (DEL) | VAF 35/275 reads (13%) | catalogued as rs1481999973, COSV63010588; called by mutect2, pindel, varscan2
- ZSWIM4 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 60/416 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1278398915; called by muse, mutect2, varscan2
- ABRA | c.608G>T p.R203M | Missense Mutation (SNP) | VAF 67/585 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- AC073111.3 | c.554A>G p.Q185R | Missense Mutation (SNP) | VAF 20/601 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.092); called by muse, mutect2
- ACSS3 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS13 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 61/467 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADGRA1 | c.482A>G p.E161G | Missense Mutation (SNP) | VAF 40/366 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- ADGRG4 | c.6347A>G p.N2116S | Missense Mutation (SNP) | VAF 50/431 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRV1 | c.18617T>C p.M6206T | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- ADIPOR1 | c.916A>G p.M306V | Missense Mutation (SNP) | VAF 15/442 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- ADK | c.312del p.F104Lfs*6 (on ENST00000286621; = p.F87Lfs*6 on NM_001123.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/264 reads (12%) | called by mutect2, pindel, varscan2
- ADRA1D | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 71/546 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADRA2B | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 19/656 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- ADRA2C | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 78/633 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGPAT1 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 58/587 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGRN | c.4106T>C p.V1369A | Missense Mutation (SNP) | VAF 58/458 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP3 | c.2447G>A p.S816N | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP4 | c.1689A>C p.K563N | Missense Mutation (SNP) | VAF 51/403 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- AL772284.1 | c.18T>A p.D6E | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ALDH4A1 | c.1505G>A p.G502D | Missense Mutation (SNP) | VAF 43/455 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALK | c.4796del p.P1599Lfs*11 | Frame Shift Del (DEL) | VAF 34/364 reads (9%) | called by mutect2, pindel
- ALS2CL | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 39/353 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ALX3 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 103/735 reads (14%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANAPC2 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 18/614 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2
- ANKRD17 | c.4166C>A p.P1389H | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD28 | c.922A>C p.T308P | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, varscan2
- ANKRD53 | c.16A>C p.S6R | Missense Mutation (SNP) | VAF 76/469 reads (16%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANLN | c.986T>C p.V329A | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANO3 | c.8A>G p.H3R | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- AP3B1 | c.2640del p.G881Dfs*2 | Frame Shift Del (DEL) | VAF 29/298 reads (10%) | called by mutect2, pindel
- APC2 | c.4888C>T p.Q1630* | Nonsense Mutation (SNP) | VAF 58/1036 reads (6%) | called by muse, mutect2
- ARC | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 70/900 reads (8%) | called by muse, mutect2
- ARFGEF1 | c.5254C>T p.Q1752* | Nonsense Mutation (SNP) | VAF 28/323 reads (9%) | called by muse, mutect2
- ARHGAP25 | c.101C>T p.A34V (on ENST00000409202 / NM_001007231.3; = p.A27V on NM_014882.3) | Missense Mutation (SNP) | VAF 44/452 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- ARHGAP32 | c.2522G>A p.S841N (on ENST00000310343 / NM_001378025.1; = p.S492N on NM_014715.4) | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ARHGDIG | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 51/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARID1A | c.970_983del p.G324Pfs*71 | Frame Shift Del (DEL) | VAF 108/909 reads (12%) | called by mutect2, pindel, varscan2
- ARL6IP6 | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 76/601 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- ARNT | c.2155A>T p.T719S | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ARSL | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 68/475 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, varscan2
- ATN1 | c.3094G>A p.A1032T | Missense Mutation (SNP) | VAF 60/478 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP13A2 | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 58/520 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP2C1 | c.2312del p.L771* | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | called by mutect2, pindel, varscan2
- ATP5ME | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 60/427 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP9B | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 50/568 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.157); called by muse, mutect2
- AXIN2 | c.1795del p.A599Pfs*90 | Frame Shift Del (DEL) | VAF 55/590 reads (9%) | called by mutect2, pindel
- AZGP1 | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 37/351 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- B3GNT5 | c.1047del p.F349Lfs*8 | Frame Shift Del (DEL) | VAF 19/127 reads (15%) | called by mutect2, pindel, varscan2
- BAZ1A | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- BIN2 | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPTF | c.2977G>A p.E993K | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BRS3 | c.1031A>G p.Q344R | Missense Mutation (SNP) | VAF 15/509 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2
- BTN3A2 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 37/566 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2
- C3 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 48/360 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- C3orf56 | c.206dup p.Q70Tfs*43 | Frame Shift Ins (INS) | VAF 40/408 reads (10%) | called by mutect2, pindel
- C6orf58 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- C8orf34 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 66/802 reads (8%) | SIFT tolerated, low confidence (0.27); called by muse, mutect2
- C9orf43 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 31/210 reads (15%) | called by muse, mutect2, varscan2
- CACNA1B | c.3733A>G p.N1245D | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CACTIN | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 78/528 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CALHM4 | c.637C>A p.L213I (on ENST00000368596 / NM_001366078.1; = p.L27I on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/421 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2
- CAMKV | c.552del p.E185Sfs*8 | Frame Shift Del (DEL) | VAF 27/219 reads (12%) | called by mutect2, pindel, varscan2
- CARMIL3 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 20/542 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); called by muse, mutect2
- CASK | c.1616T>A p.I539N | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASKIN1 | c.3777G>T p.E1259D | Missense Mutation (SNP) | VAF 26/534 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.073); called by muse, mutect2
- CASTOR2 | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 18/668 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2
- CATSPERG | c.778T>C p.Y260H | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CAVIN2 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 71/454 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CCDC106 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 78/443 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CCDC141 | c.2178dup p.W727Mfs*3 | Frame Shift Ins (INS) | VAF 23/239 reads (10%) | called by mutect2, pindel
- CCDC148 | c.1260del p.K420Nfs*15 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- CCDC175 | c.1010del p.N337Mfs*4 | Frame Shift Del (DEL) | VAF 13/136 reads (10%) | called by mutect2, pindel
- CCDC189 | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2
- CCDC63 | c.421del p.M141Cfs*21 | Frame Shift Del (DEL) | VAF 26/218 reads (12%) | called by pindel, varscan2
- CCNT2 | c.1133_1135del p.N378del | In Frame Del (DEL) | VAF 42/322 reads (13%) | called by pindel, varscan2
- CD177 | c.1021del p.R341Efs*2 | Frame Shift Del (DEL) | VAF 20/192 reads (10%) | called by mutect2, varscan2
- CDH9 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH9 | c.1074C>A p.F358L | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CDHR1 | c.1884G>T p.E628D | Missense Mutation (SNP) | VAF 96/482 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CDKL4 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKN2AIP | c.1319dup p.N441Qfs*2 | Frame Shift Ins (INS) | VAF 58/331 reads (18%) | called by mutect2, pindel, varscan2
- CELA3B | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CELF6 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 75/653 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CENPH | c.344del p.N115Tfs*16 | Frame Shift Del (DEL) | VAF 16/146 reads (11%) | called by mutect2, varscan2
- CETN3 | c.189del p.A64Lfs*4 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel, varscan2
- CFAP61 | c.898del p.I300* | Frame Shift Del (DEL) | VAF 40/299 reads (13%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 44/386 reads (11%) | called by mutect2, varscan2
- CHD5 | c.2580del p.F860Lfs*4 | Frame Shift Del (DEL) | VAF 30/285 reads (11%) | called by mutect2, pindel
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, varscan2
- CHMP7 | c.925C>A p.L309M | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- CHRNA4 | c.1234dup p.L412Pfs*6 | Frame Shift Ins (INS) | VAF 72/670 reads (11%) | called by mutect2, pindel
- CHRNA5 | c.1043T>C p.M348T | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CHST1 | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 91/673 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST7 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 94/699 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CIC | c.3347del p.P1116Qfs*45 | Frame Shift Del (DEL) | VAF 100/600 reads (17%) | called by mutect2, varscan2
- CIITA | c.2503_2507del p.F835Gfs*8 | Frame Shift Del (DEL) | VAF 60/553 reads (11%) | called by mutect2, pindel, varscan2
- CLDN16 | c.676G>C p.A226P | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CLDN3 | c.530del p.G177Afs*122 | Frame Shift Del (DEL) | VAF 94/733 reads (13%) | called by mutect2, pindel, varscan2
- CLDN8 | c.304A>G p.M102V | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CLIP1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 53/330 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNNM1 | c.2580G>T p.E860D | Missense Mutation (SNP) | VAF 52/414 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CNTNAP1 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 50/574 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.478); called by muse, mutect2
- COL24A1 | c.423del p.K141Nfs*2 | Frame Shift Del (DEL) | VAF 31/218 reads (14%) | called by mutect2, pindel, varscan2
- COL7A1 | c.2537C>T p.A846V | Missense Mutation (SNP) | VAF 80/530 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COPB2 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 33/368 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.411); called by muse, mutect2
- COPS2 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- COPS3 | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- CPEB2 | c.2657G>T p.R886M | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CSNK2A3 | c.338T>C p.F113S | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTNND2 | c.2426G>A p.W809* | Nonsense Mutation (SNP) | VAF 40/304 reads (13%) | called by muse, mutect2, varscan2
- CTSH | c.923dup p.M309Nfs*102 | Frame Shift Ins (INS) | VAF 22/231 reads (10%) | called by mutect2, pindel
- CTU2 | c.1103G>T p.S368I | Missense Mutation (SNP) | VAF 47/368 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CXorf66 | c.44dup p.N15Kfs*2 | Frame Shift Ins (INS) | VAF 32/224 reads (14%) | called by mutect2, pindel, varscan2
- CYC1 | c.496_516del p.M166_F172del | In Frame Del (DEL) | VAF 51/610 reads (8%) | called by mutect2, pindel
- CYP2S1 | c.102dup p.G35Rfs*28 | Frame Shift Ins (INS) | VAF 113/799 reads (14%) | called by mutect2, pindel, varscan2
- CYRIA | c.41del p.N14Tfs*74 | Frame Shift Del (DEL) | VAF 21/174 reads (12%) | called by mutect2, pindel, varscan2
- DAB1 | c.846del p.F282Lfs*10 (on ENST00000371231; = p.F249Lfs*10 on NM_021080.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 33/244 reads (14%) | called by mutect2, pindel, varscan2
- DCDC1 | c.1209del p.K403Nfs*6 | Frame Shift Del (DEL) | VAF 22/171 reads (13%) | called by mutect2, pindel, varscan2
- DCSTAMP | c.92A>G p.Q31R | Missense Mutation (SNP) | VAF 41/587 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.371); called by muse, mutect2
- DDX19B | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- DDX4 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHDDS | c.517del p.V173Wfs*31 | Frame Shift Del (DEL) | VAF 66/404 reads (16%) | called by mutect2, pindel, varscan2
- DHRS1 | c.576G>C p.W192C | Missense Mutation (SNP) | VAF 18/548 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2
- DHX35 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- DLGAP1 | c.214del p.R72Afs*10 | Frame Shift Del (DEL) | VAF 87/708 reads (12%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.3007A>G p.I1003V | Missense Mutation (SNP) | VAF 62/718 reads (9%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.902); called by muse, mutect2
- DNAH11 | c.12242T>C p.L4081P | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DNAH2 | c.10271A>G p.Y3424C | Missense Mutation (SNP) | VAF 52/375 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DNAH2 | c.11005G>T p.A3669S | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- DNAH2 | c.13253G>A p.G4418D | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNM1 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 57/456 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK7 | c.2955dup p.H986Sfs*28 (on ENST00000635253 / NM_001367561.1; = p.H955Sfs*28 on NM_033407.3) | Frame Shift Ins (INS) | VAF 16/141 reads (11%) | called by mutect2, pindel, varscan2
- DOP1A | c.2066T>A p.I689N | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- DPP8 | c.1741T>G p.C581G (on ENST00000341861 / NM_001320875.2; = p.C565G on NM_017743.6) | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- DSP | c.4934G>A p.R1645K | Missense Mutation (SNP) | VAF 50/398 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DST | c.12660del p.V4221* (on ENST00000361203 / NM_001374722.1; = p.V1809* on NM_015548.5) | Frame Shift Del (DEL) | VAF 30/217 reads (14%) | called by mutect2, pindel, varscan2
- DTWD1 | c.604del p.I202Lfs*4 | Frame Shift Del (DEL) | VAF 20/148 reads (14%) | called by pindel, varscan2
- DYTN | c.1140G>T p.Q380H | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- EBLN2 | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- EDNRB | c.709G>T p.D237Y (on ENST00000377211 / NM_001201397.1; = p.D147Y on NM_000115.5) | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF3A | c.1777_1779del p.E593del | In Frame Del (DEL) | VAF 77/352 reads (22%) | called by pindel, varscan2
- EP400 | c.1557del p.T520Rfs*65 | Frame Shift Del (DEL) | VAF 40/365 reads (11%) | called by mutect2, pindel, varscan2
- EPDR1 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EPHA6 | c.722dup p.I242Dfs*7 | Frame Shift Ins (INS) | VAF 44/334 reads (13%) | called by mutect2, pindel, varscan2
- EPHB4 | c.2605dup p.Q869Pfs*77 | Frame Shift Ins (INS) | VAF 75/700 reads (11%) | called by mutect2, pindel, varscan2
- ERFL | c.80del p.P27Rfs*35 | Frame Shift Del (DEL) | VAF 53/384 reads (14%) | called by mutect2, pindel, varscan2
- ERMAP | c.1171del p.L391Ffs*19 | Frame Shift Del (DEL) | VAF 41/383 reads (11%) | called by mutect2, pindel, varscan2
- ESR2 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 90/689 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- F13A1 | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- F8 | c.5669T>G p.V1890G | Missense Mutation (SNP) | VAF 53/419 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FAM171A2 | c.361A>G p.S121G | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- FAM177B | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, varscan2
- FAM181B | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 108/747 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- FAM184B | c.1656A>C p.L552F | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FAM222B | c.667del p.H223Tfs*20 | Frame Shift Del (DEL) | VAF 79/573 reads (14%) | called by mutect2, pindel, varscan2
- FBXO33 | c.1342C>A p.P448T | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FCRL3 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- FERD3L | c.286A>G p.R96G | Missense Mutation (SNP) | VAF 53/605 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- FJX1 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 83/580 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FLCN | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLT3LG | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 81/434 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLVCR2 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- FLYWCH1 | c.1298A>G p.Y433C (on ENST00000253928 / NM_001308068.2; = p.Y432C on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/550 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); called by muse, mutect2
- FMN2 | c.122del p.G41Afs*5 | Frame Shift Del (DEL) | VAF 54/443 reads (12%) | called by mutect2, varscan2
- FOCAD | c.2903C>T p.A968V | Missense Mutation (SNP) | VAF 32/377 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- FOXD4L5 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 68/1517 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); called by muse, mutect2
- FYB2 | c.1493G>T p.R498M | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- FZD1 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 52/489 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- FZR1 | c.1124del p.G375Afs*14 | Frame Shift Del (DEL) | VAF 92/648 reads (14%) | called by mutect2, pindel, varscan2
- GAB2 | c.1535del p.P512Lfs*19 (on ENST00000361507 / NM_080491.3; = p.P474Lfs*19 on NM_012296.3) | Frame Shift Del (DEL) | VAF 35/313 reads (11%) | called by mutect2, pindel, varscan2
- GEMIN5 | c.4509C>A p.C1503* | Nonsense Mutation (SNP) | VAF 12/303 reads (4%) | called by muse, mutect2
- GIN1 | c.174del p.K58Nfs*6 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- GLRB | c.1092del p.A365Pfs*22 | Frame Shift Del (DEL) | VAF 41/451 reads (9%) | called by mutect2, pindel
- GOLGA4 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- GOLGA6L22 | c.232-1G>T p.X78_splice | Splice Site (SNP) | VAF 12/494 reads (2%) | called by muse, mutect2
- GOLGA6L4 | c.1137A>C p.E379D | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); called by mutect2, varscan2
- GON4L | c.1566G>A p.M522I | Missense Mutation (SNP) | VAF 42/366 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- GPRASP1 | c.1508G>A p.W503* | Nonsense Mutation (SNP) | VAF 52/602 reads (9%) | called by muse, mutect2
- GPRASP1 | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 58/455 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- GPRC5A | c.495_496del p.S166* | Frame Shift Del (DEL) | VAF 42/470 reads (9%) | called by mutect2, pindel
- GRIN2D | c.1292A>G p.H431R | Missense Mutation (SNP) | VAF 28/791 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2
- GRIP2 | c.1442G>T p.S481I (on ENST00000619221; = p.S384I on NM_001080423.4) | Missense Mutation (SNP) | VAF 45/387 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GSDMC | c.1253T>C p.M418T | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- GTPBP1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 42/437 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- GUCY1A2 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 37/519 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- GZMH | c.226del p.A76Pfs*16 | Frame Shift Del (DEL) | VAF 41/362 reads (11%) | called by mutect2, pindel, varscan2
- H2AP | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 60/530 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- H3C8 | c.45dup p.A16Sfs*9 | Frame Shift Ins (INS) | VAF 30/255 reads (12%) | called by mutect2, pindel, varscan2
- HCN1 | c.1534dup p.M512Nfs*17 | Frame Shift Ins (INS) | VAF 34/182 reads (19%) | called by mutect2, varscan2
- HNRNPL | c.1100del p.P367Hfs*28 | Frame Shift Del (DEL) | VAF 38/320 reads (12%) | called by mutect2, pindel
- HNRNPR | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 59/420 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HRNR | c.1787G>A p.G596D | Missense Mutation (SNP) | VAF 56/682 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.125); called by muse, mutect2
- HS2ST1 | c.6dup p.L3_?2 | Frame Shift Ins (INS) | VAF 35/293 reads (12%) | called by mutect2, pindel, varscan2
- HS3ST3A1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 81/643 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HS6ST3 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 48/453 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.4638G>T p.E1546D | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- IGHG1 | c.6del p.T3Pfs*35 | Frame Shift Del (DEL) | VAF 45/385 reads (12%) | called by mutect2, pindel, varscan2
- IGLV3-12 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- IGSF9B | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- INPP5B | c.2595C>A p.D865E (on ENST00000373023; = p.D785E on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- INTS2 | c.1576T>G p.F526V | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IQANK1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 61/542 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- IQCA1 | c.1055del p.N352Tfs*44 | Frame Shift Del (DEL) | VAF 14/148 reads (9%) | called by mutect2, pindel
- IQCM | c.439del p.M147Wfs*39 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- IRX3 | c.984dup p.V329Rfs*137 | Frame Shift Ins (INS) | VAF 76/728 reads (10%) | called by mutect2, pindel
- ITPR3 | c.5776G>T p.G1926W | Missense Mutation (SNP) | VAF 65/547 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITSN1 | c.43T>A p.W15R | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ITSN1 | c.3071A>G p.Q1024R | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- JARID2 | c.1186del p.A396Rfs*18 | Frame Shift Del (DEL) | VAF 62/478 reads (13%) | called by mutect2, varscan2
- JPH4 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 48/404 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KAT14 | c.629del p.P210Qfs*3 | Frame Shift Del (DEL) | VAF 42/293 reads (14%) | called by mutect2, pindel, varscan2
- KBTBD11 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 103/893 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- KCNH2 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 99/790 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ2 | c.865A>G p.N289D | Missense Mutation (SNP) | VAF 13/397 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.103); called by muse, mutect2
- KCNK9 | c.973del p.H325Tfs*18 | Frame Shift Del (DEL) | VAF 46/468 reads (10%) | called by mutect2, pindel, varscan2
- KCNN2 | c.199G>A p.V67M (on ENST00000264773; = p.V279M on NM_021614.4) | Missense Mutation (SNP) | VAF 62/510 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- KCTD15 | c.604T>C p.C202R | Missense Mutation (SNP) | VAF 81/591 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KCTD6 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- KDM4E | c.1313G>A p.G438D | Missense Mutation (SNP) | VAF 50/535 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2
- KDM6B | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 55/850 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2
- KDM6B | c.4183_4185del p.N1395del | In Frame Del (DEL) | VAF 38/362 reads (10%) | called by pindel, varscan2
- KHDRBS2 | c.748del p.A250Hfs*60 | Frame Shift Del (DEL) | VAF 39/371 reads (11%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.10613A>G p.K3538R | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2
- KIAA1217 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- KIAA1671 | c.3059C>A p.P1020H | Missense Mutation (SNP) | VAF 39/397 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- KIAA2012 | c.2208del p.V737Wfs*25 | Frame Shift Del (DEL) | VAF 33/324 reads (10%) | called by mutect2, pindel
- KIF9 | c.1801T>G p.S601A (on ENST00000265529 / NM_001377474.1; = p.S536A on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/339 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMO | c.1283del p.F428Sfs*5 | Frame Shift Del (DEL) | VAF 26/242 reads (11%) | called by mutect2, pindel
- KMT2B | c.5636dup p.V1880Cfs*92 | Frame Shift Ins (INS) | VAF 86/640 reads (13%) | called by mutect2, pindel, varscan2
- KMT2C | c.14099C>T p.P4700L | Missense Mutation (SNP) | VAF 48/359 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KNTC1 | c.4654-1G>A p.X1552_splice | Splice Site (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- KPNA7 | c.994del p.Q332Sfs*18 | Frame Shift Del (DEL) | VAF 49/457 reads (11%) | called by mutect2, pindel, varscan2
- KREMEN2 | c.775A>G p.T259A | Missense Mutation (SNP) | VAF 48/906 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.373); called by muse, mutect2
- KRT33A | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KRT78 | c.1121dup p.V375Gfs*85 | Frame Shift Ins (INS) | VAF 61/437 reads (14%) | called by mutect2, pindel, varscan2
- KRT80 | c.979A>C p.I327L | Missense Mutation (SNP) | VAF 38/354 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT84 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.24); called by muse, mutect2
- LAMA1 | c.4397G>T p.C1466F | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMC3 | c.2846G>T p.R949M | Missense Mutation (SNP) | VAF 47/420 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- LANCL3 | c.583C>G p.P195A | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LHCGR | c.774del p.K258Nfs*16 | Frame Shift Del (DEL) | VAF 42/344 reads (12%) | called by mutect2, pindel, varscan2
- LILRA1 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 91/626 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LIM2 | c.319del p.S107Pfs*43 (on ENST00000596399 / NM_001161748.2; = p.S149Pfs*43 on NM_030657.4) | Frame Shift Del (DEL) | VAF 36/269 reads (13%) | called by mutect2, pindel, varscan2
- LLGL2 | c.1510del p.R504Gfs*30 | Frame Shift Del (DEL) | VAF 46/370 reads (12%) | called by mutect2, pindel, varscan2
- LMTK3 | c.3507del p.R1169Sfs*147 | Frame Shift Del (DEL) | VAF 150/906 reads (17%) | called by mutect2, pindel, varscan2
- LRBA | c.7146G>T p.M2382I | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); called by muse, mutect2
- LRP1B | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LRP8 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 70/518 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- LRRC36 | c.1464del p.K488Nfs*77 | Frame Shift Del (DEL) | VAF 28/260 reads (11%) | called by mutect2, pindel, varscan2
- LRRC8D | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 48/360 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- LST1 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 69/545 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- LZTS2 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 15/498 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAP4K2 | c.2368del p.A790Pfs*59 | Frame Shift Del (DEL) | VAF 56/393 reads (14%) | called by mutect2, pindel, varscan2
- MAPK8IP3 | c.2926C>T p.Q976* | Nonsense Mutation (SNP) | VAF 52/456 reads (11%) | called by muse, mutect2, varscan2
- MAPRE3 | c.543del p.C182Afs*31 | Frame Shift Del (DEL) | VAF 42/380 reads (11%) | called by mutect2, varscan2
- MARCHF10 | c.22A>G p.R8G | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MARCHF4 | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 32/616 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2
- MDGA2 | c.279C>T p.Y93= | Splice Region (SNP) | VAF 43/472 reads (9%) | called by muse, mutect2
- ME1 | c.706T>C p.Y236H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MEAK7 | c.1072_1075del p.G358Wfs*115 | Frame Shift Del (DEL) | VAF 47/238 reads (20%) | called by mutect2, pindel, varscan2
- MED12 | c.6357dup p.Q2120Tfs*45 | Frame Shift Ins (INS) | VAF 60/553 reads (11%) | called by pindel, varscan2
- MED16 | c.1587G>A p.M529I | Missense Mutation (SNP) | VAF 45/612 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.079); called by muse, mutect2
- METTL4 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- METTL7A | c.247del p.A83Pfs*12 | Frame Shift Del (DEL) | VAF 48/475 reads (10%) | called by mutect2, pindel, varscan2
- MFSD6 | c.2172G>A p.Q724= | Splice Region (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- MFSD6L | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 59/472 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MMP11 | c.357G>A p.W119* | Nonsense Mutation (SNP) | VAF 52/506 reads (10%) | called by muse, mutect2
- MNX1 | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 78/701 reads (11%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MON1A | c.830G>A p.S277N | Missense Mutation (SNP) | VAF 26/511 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- MRI1 | c.133-1G>A p.X45_splice | Splice Site (SNP) | VAF 48/318 reads (15%) | called by muse, mutect2, varscan2
- MRPL2 | c.839del p.G280Afs*13 | Frame Shift Del (DEL) | VAF 61/550 reads (11%) | called by mutect2, pindel, varscan2
- MRPL3 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 21/254 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2
- MS4A5 | c.509T>C p.L170S | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MSR1 | c.284A>G p.Q95R | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by muse, mutect2
- MTSS2 | c.2135del p.P712Qfs*56 | Frame Shift Del (DEL) | VAF 68/509 reads (13%) | called by mutect2, pindel, varscan2
- MUC17 | c.3272T>G p.M1091R | Missense Mutation (SNP) | VAF 32/584 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- MUC5B | c.3023C>T p.T1008I | Missense Mutation (SNP) | VAF 59/449 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC6 | c.3439T>C p.Y1147H | Missense Mutation (SNP) | VAF 107/693 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MYH11 | c.2987A>C p.K996T | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2
- MYO1C | c.2450del p.L817Cfs*2 (on ENST00000648651 / NM_001080779.2; = p.L782Cfs*2 on NM_033375.5) | Frame Shift Del (DEL) | VAF 66/410 reads (16%) | called by mutect2, varscan2
- NADK2 | c.106del p.R36Gfs*62 | Frame Shift Del (DEL) | VAF 35/321 reads (11%) | called by mutect2, pindel, varscan2
- NCAM1 | c.2473G>A p.A825T (on ENST00000316851 / NM_181351.5; = p.A815T on NM_000615.7) | Missense Mutation (SNP) | VAF 44/311 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCKAP5 | c.2730dup p.T911Hfs*4 | Frame Shift Ins (INS) | VAF 52/544 reads (10%) | called by mutect2, pindel
- NDUFA8 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- NEIL3 | c.513del p.K171Nfs*7 | Frame Shift Del (DEL) | VAF 38/249 reads (15%) | called by mutect2, pindel, varscan2
- NEK1 | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); called by muse, varscan2
- NES | c.3406G>T p.G1136C | Missense Mutation (SNP) | VAF 26/518 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- NETO1 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2
- NIBAN1 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NISCH | c.2933A>G p.Y978C | Missense Mutation (SNP) | VAF 85/586 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NKPD1 | c.2041G>A p.G681R | Missense Mutation (SNP) | VAF 84/468 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, varscan2
- NKX3-2 | c.368T>C p.L123S | Missense Mutation (SNP) | VAF 20/712 reads (3%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.023); called by muse, mutect2
- NOL4 | c.1723G>A p.G575R | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NOVA1 | c.1213dup p.L405Pfs*21 | Frame Shift Ins (INS) | VAF 41/374 reads (11%) | called by mutect2, pindel, varscan2
- NPFFR1 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 41/431 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NR4A2 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 55/474 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- NRG3 | c.148del p.R50Gfs*53 | Frame Shift Del (DEL) | VAF 32/308 reads (10%) | called by mutect2, pindel, varscan2
- NRXN3 | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- NUDT2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP160 | c.2215C>T p.Q739* | Nonsense Mutation (SNP) | VAF 44/295 reads (15%) | called by muse, mutect2, varscan2
- NUP205 | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- OPHN1 | c.1890del p.K631Sfs*76 | Frame Shift Del (DEL) | VAF 57/466 reads (12%) | called by mutect2, pindel, varscan2
- OR2D2 | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR4Q3 | c.23T>C p.L8S | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR5AC1 | c.380T>C p.M127T | Missense Mutation (SNP) | VAF 27/276 reads (10%) | called by muse, mutect2, varscan2
- OR6C74 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- OR8J2 | c.185del p.F62Sfs*73 | Frame Shift Del (DEL) | VAF 38/283 reads (13%) | called by mutect2, pindel, varscan2
- OXTR | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 20/660 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PADI1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 34/337 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PBLD | c.391del p.Q131Rfs*6 | Frame Shift Del (DEL) | VAF 40/263 reads (15%) | called by mutect2, pindel, varscan2
- PCDH9 | c.2078C>A p.P693H | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.6664G>C p.D2222H | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.872); called by muse, mutect2
- PDIA4 | c.1243del p.L415Wfs*26 (on ENST00000286091 / NM_001371244.1; = p.L414Wfs*26 on NM_004911.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 49/387 reads (13%) | called by mutect2, pindel, varscan2
- PDSS1 | c.1208T>G p.L403R | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PFAS | c.2728G>A p.V910I | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PHKG2 | c.939G>A p.W313* | Nonsense Mutation (SNP) | VAF 50/399 reads (13%) | called by muse, mutect2, varscan2
- PIANP | c.805del p.A269Lfs*6 | Frame Shift Del (DEL) | VAF 56/474 reads (12%) | called by mutect2, pindel, varscan2
- PIK3C2B | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 45/388 reads (12%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLAAT5 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 64/370 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- PLCB3 | c.388-1G>T p.X130_splice | Splice Site (SNP) | VAF 36/275 reads (13%) | called by muse, mutect2, varscan2
- PLCD3 | c.721del p.A241Lfs*11 | Frame Shift Del (DEL) | VAF 46/469 reads (10%) | called by mutect2, pindel
- PLCG2 | c.2912C>A p.P971H | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCL1 | c.3206G>A p.S1069N | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PLGRKT | c.183del p.F61Lfs*8 | Frame Shift Del (DEL) | VAF 34/238 reads (14%) | called by mutect2, varscan2
- PLVAP | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 83/527 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PLXNB1 | c.955T>G p.S319A | Missense Mutation (SNP) | VAF 73/673 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PNMT | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 59/587 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- POTEA | c.1323del p.F441Lfs*32 (on ENST00000519951 / NM_001005365.2; = p.F395Lfs*32 on NM_001002920.1) | Frame Shift Del (DEL) | VAF 21/187 reads (11%) | called by mutect2, pindel, varscan2
- PPFIBP2 | c.210_211del p.R70Sfs*20 | Frame Shift Del (DEL) | VAF 52/437 reads (12%) | called by pindel, varscan2
- PPIF | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 41/385 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); called by muse, mutect2
- PPP1CA | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PPP4R3C | c.955_956del p.Q319Vfs*4 | Frame Shift Del (DEL) | VAF 30/182 reads (16%) | called by pindel, varscan2
- PPP6R2 | c.2688dup p.E897Rfs*103 (on ENST00000216061 / NM_001365836.1; = p.E863Rfs*103 on NM_014678.5 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 78/719 reads (11%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- PROSER3 | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); called by muse, mutect2
- PRR12 | c.1184del p.G395Afs*7 (on ENST00000615927; = p.G1216Afs*7 on NM_020719.3) | Frame Shift Del (DEL) | VAF 77/620 reads (12%) | called by mutect2, pindel, varscan2
- PRR33 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 54/456 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, varscan2
- PRRC2C | c.883C>T p.R295C (on ENST00000367742; = p.R293C on NM_015172.4) | Missense Mutation (SNP) | VAF 27/373 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRRT1B | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 56/580 reads (10%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.082); called by muse, mutect2
- PRSS12 | c.2500C>A p.P834T | Missense Mutation (SNP) | VAF 54/506 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.13); called by muse, mutect2
- PSEN1 | c.870A>G p.S290= | Splice Region (SNP) | VAF 36/244 reads (15%) | called by muse, mutect2, varscan2
- PTPRG | c.4183A>G p.T1395A | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PTPRO | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- QRICH2 | c.2115G>T p.L705F | Missense Mutation (SNP) | VAF 83/684 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- RAE1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAVER2 | c.822dup p.A275Cfs*4 | Frame Shift Ins (INS) | VAF 35/285 reads (12%) | called by mutect2, pindel, varscan2
- RBM25 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 60/488 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RBMXL3 | c.238A>G p.M80V | Missense Mutation (SNP) | VAF 79/607 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
485 further variants in this file (131 protein-altering or splice-affecting, 306 silent, 48 other) are not listed here.
